Gene-level copy-number profile of tumor specimen TCGA-KK-A59X-01A from TCGA case TCGA-KK-A59X, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,416 days).
Specimen TCGA-KK-A59X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.7167064c-5e06-4641-9b55-7a968f550f7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A59X-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9aa40c2d-a16d-425b-8903-6927aaa10807

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 10,288; copy number 2: 49,413; copy number 3: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A59X-01A-11D-A323-01): tumor purity 0.86, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:55,935,095–56,976,224, 30 genes: IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1.
- chr13:103,043,998–103,444,968, 4 genes: SLC10A2, AL162717.1, LINC01309, ATP6V1G1P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,939. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
